Surgical pathology report (de-identified scan), TCGA case TCGA-ZS-A9CE, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Tayside Tissue Bank, specimen TCGA-ZS-A9CE-01A (Primary Tumor).

[page 1 of 2]
Nature of Specimen(s)

1. Segment 6 liver
2. Gallbladder

Clinical Information Supplied

FEMALE

Hepatocellular carcinoma segment 6 resection today. PMH multiple PE's on warfarin pacemaker

Macro Report

Reurement Date:

1. Received is a segmental resection of liver measuring 120mm x 30mm x 20mm from which is attached a pedunculated tumour mass measuring 95mm x 75mm x 65mm approximately. On slicing the tumour is clear of the inked resection margin by at least 30mm. On transverse sectioning of the tumour the tumour displays a homogenous yellow tan cut face which is firm but displays flecks of black and red material. Tumour softening is not a prominent feature.

2. Received is a gallbladder measuring 52mm. The external surface is unremarkable. On opening no stones and no tumour mass are detected.

Micro Report

1. Sections confirm a well-differentiated hepatocellular carcinoma. Tumour cells are arranged in large sheets and well formed acini. The tumour cells produce bile and demonstrate a large amount of often clear cytoplasm. Nuclear atypia is moderate. Necrosis is not a common feature. Tumour cells extensively invade a tumour pseudocapsule. However the margin of resection is clear. In one block a small amount of small vessel invasion is noted.

Well differentiated hepatocellular carcinoma, completely excised.

2. Sections show unremarkable gallbladder wall. There is no evidence of malignancy.

ICD O.3

Carcinoma, hepatocellular NOS 8170/3

Date: Liver 22.0 2014/19/14

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

[page 2 of 2]
Signature of Pathologist(s)

Page 2 of 2

ACKNOWLEDGEMENT OF RECEIPT	
WARD SECRETARY	DOCTOR

Source: NCI Genomic Data Commons file 3ba89355-e686-4173-95b2-4388cbed10e2 (TCGA-ZS-A9CE.35A87F65-19F9-4C03-8A82-FFBF2C3C568A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).